MMRF case MMRF_1639 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3eea489a-673f-40bb-ad41-9b9fba7ed416

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 704 days (1.9 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.3 years (24,581 days); ISS stage: III; Days to last known disease status: 704 days (1.9 years); Days to last follow up: 704 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 575 days (1.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 210 days; Days to treatment end: 521 days (1.4 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 520 days (1.4 years); Days to treatment end: 679 days (1.9 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 657 days (1.8 years); Days to treatment end: 679 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 657 days (1.8 years); Days to treatment end: 657 days (1.8 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 704.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 357 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.36 mg/dL; Immunoglobulin G 2.61 g/L; Immunoglobulin A 73 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 5.96 µg/mL; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 4.22 mmol/L; Leukocytes 13.1 ×10⁹/L; Absolute Neutrophil 11.5 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 140 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 3.33 mmol/L; Albumin 29 g/L; Total Protein 11.7 g/dL; Glucose 5.83 mmol/L; C-Reactive Protein 4.22 mg/dL.
- Day 84 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 5.47 g/L; Immunoglobulin A 1.81 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 9.8 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 390 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 6.4 g/dL; Glucose 6.11 mmol/L.
- Day 168 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 8.46 g/L; Immunoglobulin A 3.15 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 7.58 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 4.24 mmol/L.
- Day 258 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 9.99 g/L; Immunoglobulin A 3.57 g/L; Immunoglobulin M 0.74 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 3.69 mmol/L.
- Day 531 (ECOG 1): M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 158 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 144 mg/dL; Immunoglobulin G 5.81 g/L; Immunoglobulin A 38.6 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 37 g/L; Total Protein 11.1 g/dL; Glucose 4.57 mmol/L.
- Day 623: M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 4.65 g/L; Immunoglobulin A 19.1 g/L; Immunoglobulin M 0.47 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Glucose 6.38 mmol/L.

Other clinical attributes
- Day 1: Weight: 84 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (4 samples)
- Sample MMRF_1639_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1639_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1639_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 258 days.
- Sample MMRF_1639_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 531 days (1.5 years).
